Somatic mutation profile of tumor specimen MP2PRT-PAUXKM-TMP1-A (aliquot MP2PRT-PAUXKM-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAUXKM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,447 days).
Specimen MP2PRT-PAUXKM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9bb76a0-ecd6-41c3-9b58-01f3d5919339.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUXKM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUXKM-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7546aa3d-48eb-4301-8b1b-ea29ccd4ab4c

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FSIP2 | c.1642G>C p.D548H | Missense Mutation (SNP) | VAF 187/400 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs1284281644, COSV58092618; called by muse, mutect2, varscan2
- RBMXL2 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 54/708 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.569); catalogued as rs866421802; called by muse, mutect2
- RTP1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 244/594 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs766864382; called by muse, varscan2
- WDR49 | c.1351G>C p.E451Q (on ENST00000308378 / NM_001366158.1; = p.E792Q on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as COSV100393685; called by muse, mutect2
- ZNF215 | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 135/366 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs200066448, COSV53493908; called by muse, varscan2
- DOCK4 | c.917T>C p.L306P | Missense Mutation (SNP) | VAF 41/534 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- GRM1 | c.886G>T p.V296L | Missense Mutation (SNP) | VAF 15/425 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); called by muse, mutect2
- KBTBD3 | c.340A>G p.K114E | Missense Mutation (SNP) | VAF 22/402 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2
- LHX8 | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 155/335 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- NWD2 | c.4682T>C p.V1561A | Missense Mutation (SNP) | VAF 158/369 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RGS9 | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 59/824 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.053); called by muse, mutect2
- S100B | c.276G>C p.E92D | Missense Mutation (SNP) | VAF 132/354 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- C2CD4B | c.306G>A p.A102= | Silent (SNP) | VAF 250/688 reads (36%) | called by muse, mutect2, varscan2
- RPL3L | c.93G>A p.T31= | Silent (SNP) | VAF 33/687 reads (5%) | catalogued as rs777369685; called by muse, mutect2
- SIGLEC1 | c.261C>T p.T87= | Silent (SNP) | VAF 204/445 reads (46%) | catalogued as rs760174403, COSV52468822; called by muse, mutect2, varscan2
- SPDYA | c.501C>T p.L167= | Silent (SNP) | VAF 32/310 reads (10%) | called by muse, varscan2
- UPP1 | c.909C>T p.I303= | Silent (SNP) | VAF 19/429 reads (4%) | called by muse, mutect2
